MMRF case MMRF_1859 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8529a6ca-c536-46f3-a572-81eaf7633b75

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,107 days); ISS stage: I; Days to last known disease status: 1,093 days (3.0 years); Days to last follow up: 1,093 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 262 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 262 days; Days to treatment end: 945 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 1.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 149 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.22 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.6 g/dL; Glucose 4.51 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 99 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.626 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.44 mmol/L.
- Day 211 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 15.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 6.72 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 9.32 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 263 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 266 (ECOG 0): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.081 mg/dL; Immunoglobulin G 9.79 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.97 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 154 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 5.72 mmol/L.
- Day 357 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.131 mg/dL; Immunoglobulin G 5.64 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 142 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 449 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.266 mg/dL; Immunoglobulin G 3.69 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 5.2 g/dL; Glucose 4.68 mmol/L.
- Day 547 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.779 mg/dL; Immunoglobulin G 4.66 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.9 mmol/L.
- Day 603 (ECOG 0): Hemoglobin 7.07 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 182 ×10⁹/L.
- Day 721 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.993 mg/dL; Immunoglobulin G 5 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 4.62 mmol/L.
- Day 792 (ECOG 0): Hemoglobin 7.44 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 172 ×10⁹/L.
- Day 860 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 4.05 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 4.48 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 5.61 mmol/L.
- Day 952 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.963 mg/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 1,093 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 9.89 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -8: Weight: 93 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1859_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1859_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
